Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3HS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3HS-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 5 x 4 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Tumor extent: Lesion greater than 4.0 cm

Lymph nodes: 0/10 positive for metastasis (Regional 0/10)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Gross Description:

1CD-0-3

Microscopic Description:

Carcinoma, Squamous cell 8070/3

Diagnosis Details:

Site: Cervix, NOS C53.9

hw
12/1/11

HPV Discrepancy		X
Review Initials:	hw	12/1/11

Source: NCI Genomic Data Commons file 1c0c7676-edc8-41aa-b429-5959457e3268 (TCGA-EA-A3HS.103C790B-65FE-4E6A-9CD8-C8B35BB09ABB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).